MMRF case MMRF_1731 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7ca26b63-ec44-4f12-8528-4fa8ec48de3a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.9 years (18,588 days); ISS stage: II; Days to last known disease status: 1,154 days (3.2 years); Days to last follow up: 1,154 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 35 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 9 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 24 days; Days to treatment end: 37 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 59 days; Days to treatment end: 59 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 69 days; Days to treatment end: 69 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 84 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 755 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 434 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 241 mg/dL; Immunoglobulin G 5.72 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 0.516 µg/mL; Hemoglobin 5.46 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 355 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 1.85 mmol/L; Albumin 29 g/L; Total Protein 5.4 g/dL; Glucose 6.49 mmol/L.
- Day 106 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.595 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 3.36 µg/mL; Lactate Dehydrogenase 12.7 µkat/L; Hemoglobin 4.71 mmol/L; Leukocytes 30.7 ×10⁹/L; Absolute Neutrophil 26.1 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2 mmol/L; Albumin 31 g/L; Total Protein 5.1 g/dL; Glucose 5.34 mmol/L.
- Day 182 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.925 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 3.11 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 1.42 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 4.62 mmol/L.
- Day 273 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.849 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.602 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 1.47 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 5.9 g/dL; Glucose 4.18 mmol/L.
- Day 364 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.728 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.733 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 1.55 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 455 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.769 mg/dL; Immunoglobulin G 6.68 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 553 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 1.47 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 4.73 mmol/L.
- Day 644 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.488 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 1.43 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 735 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 7.6 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 1.33 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 4.46 mmol/L.
- Day 811 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.76 mg/dL; Immunoglobulin G 7.03 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 1.42 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 3.85 mmol/L.
- Day 917 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.66 mg/dL; Immunoglobulin G 6.25 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 1.37 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.95 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 3.91 mmol/L.
- Day 1,000 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.781 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.817 mg/dL; Immunoglobulin G 4.51 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 1.2 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 4.29 mmol/L.
- Day 1,072 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 4.28 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 4.79 mmol/L.
- Day 1,154 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.677 mg/dL; Immunoglobulin G 3.51 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 1.5 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day 1: Weight: 45 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_1731_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1731_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1731_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 735 days (2.0 years).
